Somatic mutation profile of tumor specimen TCGA-CU-A3KJ-01A (aliquot TCGA-CU-A3KJ-01A-11D-A21A-08) from TCGA case TCGA-CU-A3KJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.8 years (27,692 days).
Specimen TCGA-CU-A3KJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 732dea16-7bb1-4962-9b76-88c06302c4fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CU-A3KJ-10A (Blood Derived Normal), aliquot TCGA-CU-A3KJ-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc2179e4-eae2-44bf-af3f-ae72ce78e702

The open-access MAF lists 259 somatic variants for this specimen: 182 protein-altering or splice-affecting, 67 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 67, Nonsense Mutation 14, Intron 4, Splice Site 3, 5'UTR 3, RNA 2, In Frame Del 2, Frame Shift Del 1, Frame Shift Ins 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4933C>T p.R1645* | Nonsense Mutation (SNP) | VAF 38/53 reads (72%) | catalogued as rs139310551, CM153495, COSV54327123, COSV54342894; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRS | c.4475G>A p.R1492Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs770889503, CM155628, COSV53625667; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 76/100 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTA2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 66/86 reads (77%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as COSV56518145; called by muse, mutect2, varscan2
- ADAM29 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV63668153; called by muse, mutect2, varscan2
- ADGRG3 | c.808C>A p.R270S | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.392); catalogued as COSV59651947, COSV59652653; called by muse, mutect2, varscan2
- AFMID | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV59977569; called by muse, mutect2, varscan2
- ALAS1 | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59629644; called by muse, mutect2, varscan2
- ANK1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV55895836; called by muse, mutect2, varscan2
- ANO9 | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.292); catalogued as rs1271384417, COSV60385360; called by muse, mutect2, varscan2
- AP2A1 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 106/279 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.144); catalogued as rs775953622, COSV62819241; called by muse, mutect2, varscan2
- APLP1 | c.1813C>A p.R605S (on ENST00000221891 / NM_001024807.3; = p.R604S on NM_005166.4) | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104381209, COSV55706913; called by muse, mutect2, varscan2
- APOB | c.13487G>C p.R4496T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV51922834, COSV51952204, COSV51952606; called by muse, mutect2, varscan2
- ARID1A | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV61370682, COSV61388619, COSV61391065; called by muse, mutect2, varscan2
- ATF7IP | c.3136C>T p.Q1046* | Nonsense Mutation (SNP) | VAF 45/94 reads (48%) | catalogued as COSV53774800; called by muse, mutect2, varscan2
- ATP6V1B1 | c.446-1G>A p.X149_splice | Splice Site (SNP) | VAF 39/169 reads (23%) | catalogued as rs1363121734, COSV52272009; called by muse, mutect2, varscan2
- BTG2 | c.292_293del p.S98Rfs*10 | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | catalogued as COSV51858200; called by mutect2, pindel, varscan2
- C1GALT1 | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1486027322, COSV56180422; called by muse, mutect2, varscan2
- C2orf16 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV68646966; called by muse, mutect2, varscan2
- CADM2 | c.832G>C p.G278R (on ENST00000407528 / NM_001167674.2; = p.G280R on NM_153184.4) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67385875, COSV67404076; called by muse, mutect2, varscan2
- CAST | c.1445G>A p.R482K (on ENST00000341926; = p.R565K on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57789436; called by muse, mutect2, varscan2
- CBLL2 | c.788G>A p.C263Y | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1280374517, COSV60370281; called by muse, mutect2, varscan2
- CDCA3 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV57530364; called by muse, varscan2
- CDH7 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as rs1239000535, COSV59894574; called by muse, mutect2, varscan2
- CLCN1 | c.1727C>G p.S576C | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143825889; called by muse, mutect2, varscan2
- CNNM2 | c.1805G>T p.R602L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as COSV63998186, COSV64002192; called by mutect2, varscan2
- COP1 | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58176021; called by muse, mutect2, varscan2
- CPEB1 | c.1567G>C p.D523H (on ENST00000617958; = p.D458H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55621554, COSV99917797; called by muse, mutect2, varscan2
- CTSB | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs144771892; called by muse, mutect2, varscan2
- CUBN | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564519531, COSV64727145; called by muse, mutect2, varscan2
- CUTC | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV65081802; called by muse, mutect2, varscan2
- DBP | c.840G>C p.E280D | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55342209; called by muse, mutect2, varscan2
- DDR2 | c.2551C>A p.Q851K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV63374403; called by muse, varscan2
- DGKG | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 124/505 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs779678089, COSV53972704; called by muse, mutect2, varscan2
- DLG1 | c.2173G>C p.D725H (on ENST00000419354 / NM_001290983.1; = p.D747H on NM_004087.2) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58391383; called by muse, mutect2, varscan2
- DNAH17 | c.9916G>C p.E3306Q | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV67761078; called by muse, mutect2, varscan2
- DOCK8 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV66632992; called by muse, mutect2, varscan2
- DPY19L3 | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV60480148; called by muse, mutect2, varscan2
- DSG1 | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.919); catalogued as COSV57139300; called by muse, mutect2, varscan2
- DTX2 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 76/687 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV56865114; called by muse, mutect2
- DUOX2 | c.3566G>A p.G1189D | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1341543810, COSV66534639; called by muse, mutect2, varscan2
- DUSP6 | c.839-1G>A p.X280_splice | Splice Site (SNP) | VAF 16/43 reads (37%) | catalogued as COSV54379520; called by muse, mutect2, varscan2
- EIF3L | c.665G>A p.W222* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV101094413; called by muse, mutect2, varscan2
- EP300 | c.5217C>G p.I1739M | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54345452; called by muse, mutect2, varscan2
- EP300 | c.6004C>G p.Q2002E | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.376); catalogued as COSV54331349, COSV54345469; called by muse, mutect2, varscan2
- ESD | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV66340896; called by muse, mutect2, varscan2
- EXOC1 | c.581G>C p.R194T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV62121910, COSV62121995; called by muse, mutect2, varscan2
- FASTKD2 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV52700211; called by muse, mutect2, varscan2
- FLRT2 | c.1004G>T p.R335L | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58149836, COSV58150136; called by muse, mutect2, varscan2
- FMN2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60434714; called by muse, mutect2, varscan2
- FNDC3A | c.1910G>A p.R637Q (on ENST00000492622 / NM_001079673.2; = p.R581Q on NM_014923.5) | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs764785324, COSV68135085; called by muse, mutect2, varscan2
- FTO | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51668619; called by muse, mutect2, varscan2
- GBP1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV65084510; called by muse, mutect2, varscan2
- GBP1 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV65084515; called by muse, mutect2, varscan2
- GFRA1 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62610701; called by muse, mutect2, varscan2
- GIT1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56612708; called by muse, mutect2, varscan2
- GNAL | c.700G>A p.V234I (on ENST00000269162 / NM_001142339.3; = p.V311I on NM_182978.4) | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CM165376, COSV52333987; called by muse, mutect2, varscan2
- GNB3 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 180/475 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV57530360, COSV99977001; called by muse, mutect2, varscan2
- GNPTG | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as COSV50190803; called by muse, mutect2, varscan2
- GOLGA5 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375552804; called by muse, mutect2, varscan2
- GPR161 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54794629; called by muse, mutect2, varscan2
- GRINA | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV57593577; called by muse, mutect2, varscan2
- HIP1 | c.1145G>C p.R382T | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV61191481; called by muse, varscan2
- HSP90B1 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV55357892; called by muse, mutect2, varscan2
- IFI44L | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV60729435; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.263C>A p.T88N | Missense Mutation (SNP) | VAF 71/520 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs765917324; called by muse, mutect2, varscan2
- IL10RA | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV57142119; called by muse, mutect2
- INO80D | c.1477T>G p.C493G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68960057; called by mutect2, varscan2
- INTS1 | c.3431C>T p.S1144L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs375215357; called by muse, mutect2, varscan2
- JAK3 | c.1576A>G p.N526D | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.634); catalogued as COSV71687742; called by muse, mutect2, varscan2
- KBTBD7 | c.1035G>T p.M345I | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65267155; called by muse, mutect2, varscan2
- KCNK2 | c.217C>G p.L73V (on ENST00000444842 / NM_001017425.3; = p.L58V on NM_014217.4) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV67207459; called by muse, mutect2, varscan2
- KDM6A | c.3578G>A p.W1193* | Nonsense Mutation (SNP) | VAF 10/12 reads (83%) | catalogued as COSV100938625; called by muse, mutect2, varscan2
- KIAA1841 | c.1548A>G p.I516M | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1399068221, COSV54378870; called by muse, mutect2, varscan2
- KNL1 | c.991G>A p.E331K (on ENST00000346991 / NM_170589.5; = p.E305K on NM_144508.5) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1232745161, COSV61160376; called by muse, mutect2, varscan2
- KRT6C | c.988C>A p.L330M | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV52880542; called by muse, mutect2, varscan2
- KRT6C | c.987C>A p.D329E | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52880551; called by muse, mutect2, varscan2
- KRTAP5-11 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 77/260 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV59371964; called by muse, mutect2, varscan2
- LAMC2 | c.3015G>C p.Q1005H | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as rs749008433, COSV51456500; called by muse, mutect2, varscan2
- LAMC2 | c.3154G>C p.E1052Q | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.368); catalogued as COSV51459723; called by muse, mutect2, varscan2
- LBR | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.046); catalogued as rs765875442, COSV55288281; called by muse, mutect2, varscan2
- LMNB2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV57590762; called by muse, mutect2, varscan2
- LPIN1 | c.2666C>T p.S889L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs374190632; called by muse, mutect2, varscan2
- LRRC4 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV50818435; called by muse, mutect2, varscan2
- LYST | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as COSV67713961; called by muse, mutect2, varscan2
- MANEA | c.1123A>G p.N375D | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV62590592; called by muse, mutect2, varscan2
- MAP1B | c.5075C>G p.S1692C | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV57106366; called by muse, mutect2, varscan2
- MEI1 | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as rs1319910802, COSV55907817; called by muse, mutect2, varscan2
- MRS2 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV51235542; called by muse, mutect2, varscan2
- MSH4 | c.735C>A p.F245L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54211972; called by muse, mutect2, varscan2
- NAA15 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.185); catalogued as COSV56722660; called by muse, mutect2, varscan2
- NAALAD2 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV58966104; called by muse, varscan2
- NAV1 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV55226333; called by muse, varscan2
- NDST3 | c.2114A>G p.Y705C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56629302; called by muse, mutect2, varscan2
- NEBL | c.2342C>G p.S781* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV65801919; called by muse, mutect2, varscan2
- NFATC2 | c.893C>G p.A298G | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as COSV65359088; called by muse, varscan2
- NMU | c.257T>C p.M86T | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1185492279, COSV51701972; called by muse, mutect2, varscan2
- NRXN1 | c.2386G>C p.E796Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV58459244, COSV58493099; called by muse, mutect2, varscan2
- NSUN3 | c.143C>G p.S48* | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | catalogued as COSV58936652; called by muse, mutect2, varscan2
- NSUN6 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs772354397, COSV66035358; called by muse, mutect2, varscan2
- NUS1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs150953098; called by muse, mutect2, varscan2
- ODF4 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 90/124 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV60273085; called by muse, mutect2, varscan2
- OPA1 | c.2786G>C p.C929S (on ENST00000361510 / NM_130837.3; = p.C874S on NM_015560.3) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62483386; called by muse, mutect2, varscan2
- OR13F1 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV58252636; called by muse, mutect2, varscan2
- PAN2 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777411298, COSV57756099; called by muse, mutect2, varscan2
- PATJ | c.2764C>G p.Q922E | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV57172154; called by muse, mutect2, varscan2
- PCDH1 | c.3485G>A p.G1162E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as COSV54619445; called by muse, mutect2, varscan2
- PCDH1 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs149443924; called by muse, mutect2, varscan2
- PCDHGB7 | c.955A>T p.I319L | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV54032666; called by muse, mutect2, varscan2
- PCNT | c.2905G>C p.D969H | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV64033018; called by muse, mutect2, varscan2
- PI15 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52644402; called by muse, mutect2, varscan2
- PLEKHH2 | c.4193T>C p.M1398T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56761166; called by muse, mutect2, varscan2
- PLEKHO2 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV60261529, COSV60262962; called by muse, mutect2, varscan2
- PLEKHO2 | c.981G>C p.E327D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60262970; called by muse, mutect2, varscan2
- PLEKHO2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV60262977, COSV60263190; called by muse, mutect2, varscan2
- PNPLA6 | c.3764G>A p.G1255E (on ENST00000414982 / NM_001166111.2; = p.G1207E on NM_006702.5) | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as COSV55384881; called by muse, mutect2, varscan2
- PRRT2 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV54886453; called by muse, mutect2, varscan2
- PTPRK | c.3004G>C p.D1002H (on ENST00000368215 / NM_001291984.2; = p.D1003H on NM_002844.4) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV63904062, COSV63907082; called by muse, mutect2, varscan2
- PTPRM | c.1841G>C p.R614T | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59881614; called by muse, mutect2, varscan2
- PUM1 | c.720+1G>A p.X240_splice | Splice Site (SNP) | VAF 39/71 reads (55%) | catalogued as COSV57084300, COSV57091242; called by muse, mutect2, varscan2
- RASIP1 | c.2872C>G p.P958A | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.026); catalogued as COSV55808409; called by muse, mutect2, varscan2
- RELCH | c.2014G>C p.D672H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56892195; called by muse, mutect2, varscan2
- RHOQ | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV53191068; called by muse, mutect2, varscan2
- RNF213 | c.3014C>G p.S1005* | Nonsense Mutation (SNP) | VAF 52/91 reads (57%) | catalogued as rs768806630, COSV100174010; called by muse, mutect2, varscan2
- RNF220 | c.340C>G p.H114D | Missense Mutation (SNP) | VAF 115/201 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV62409710; called by muse, mutect2, varscan2
- RNF7 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV56422352; called by muse, mutect2
- RSPH6A | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV55575485; called by muse, mutect2, varscan2
- RYR3 | c.14186T>G p.I4729S (on ENST00000389232; = p.I4730S on NM_001036.6) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM142577, COSV66808346; called by muse, mutect2, varscan2
- SCFD1 | c.1362G>C p.M454I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV61727282; called by muse, mutect2, varscan2
- SDK1 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765510202, COSV67388387; called by muse, mutect2, varscan2
- SENP5 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV60210443; called by muse, mutect2, varscan2
- SH3BP4 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.153); catalogued as COSV60646423; called by muse, mutect2
- SLC25A30 | c.617C>G p.S206* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as rs1336412433, COSV60433950; called by muse, mutect2, varscan2
- SLC26A8 | c.1526C>G p.S509* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV62885083; called by muse, mutect2, varscan2
- SLC30A1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as rs767899380, COSV65360857; called by mutect2, varscan2
- SMARCA4 | c.3099G>C p.K1033N | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60809194; called by muse, mutect2, varscan2
- SNTB1 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV67327398, COSV67329295; called by muse, mutect2, varscan2
- SPATA5 | c.2405G>A p.R802K | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56784441; called by muse, varscan2
- SPEN | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1405372960, COSV65360747; called by muse, mutect2, varscan2
- SRSF6 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV54829113; called by muse, mutect2, varscan2
- STIL | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54553793; called by muse, mutect2, varscan2
- STMN2 | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV55219904, COSV55222549; called by muse, mutect2, varscan2
- STPG1 | c.460A>T p.N154Y (on ENST00000337248 / NM_001199013.2; = p.N107Y on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV50225156; called by muse, mutect2, varscan2
- SYNE1 | c.25192G>C p.E8398Q (on ENST00000367255 / NM_182961.4; = p.E8350Q on NM_033071.3) | Missense Mutation (SNP) | VAF 66/82 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55100571; called by muse, mutect2, varscan2
- SYNE1 | c.9730C>G p.Q3244E (on ENST00000367255 / NM_182961.4; = p.Q3251E on NM_033071.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV55100635; called by muse, varscan2
- TAFA4 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV55145942, COSV99807726; called by muse, mutect2, varscan2
- TBL3 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60343083; called by muse, mutect2, varscan2
- TCN1 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57254718; called by muse, mutect2, varscan2
- TENM3 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.968); catalogued as rs753954357, COSV69313967; called by muse, mutect2, varscan2
- TNFRSF8 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55800758; called by muse, mutect2, varscan2
- TNS1 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1476661290, COSV50739506, COSV99409855; called by muse, mutect2, varscan2
- TRIB2 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50230966; called by muse, mutect2, varscan2
- TSPAN4 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60260662; called by muse, mutect2, varscan2
- TTYH1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56615439; called by muse, mutect2, varscan2
- UGT2B11 | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV71424403; called by muse, mutect2, varscan2
- WDR76 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV55479455; called by muse, mutect2, varscan2
- YAF2 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV59892573; called by mutect2, varscan2
- ZNF10 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV50212776; called by muse, mutect2, varscan2
- ZNF32 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65641977; called by muse, mutect2, varscan2
- ZNF550 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as rs1238555052, COSV57306722; called by muse, mutect2, varscan2
- ZNF594 | c.935A>G p.E312G | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.091); catalogued as COSV68386210; called by muse, mutect2, varscan2
- ZNF721 | c.1454G>T p.G485V (on ENST00000338977; = p.G497V on NM_133474.4) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59097110; called by muse, mutect2, varscan2
- ZNF99 | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV68057046; called by mutect2, varscan2
- ZSCAN22 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV61639618; called by muse, mutect2
- ZZZ3 | c.2567G>C p.C856S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); catalogued as COSV66235512; called by mutect2, varscan2
- ACACA | c.4240C>G p.L1414V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, varscan2
- AFF1 | c.3130G>C p.E1044Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2
- ASCL1 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- CLIC5 | c.583C>T p.Q195* (on ENST00000185206 / NM_001370649.1; = p.Q36* on NM_016929.5) | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1584C>A p.F528L | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FMN2 | c.590C>G p.S197* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- FREM2 | c.7910G>A p.W2637* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- GPR107 | c.1569G>A p.W523* (on ENST00000372406 / NM_001136557.2; = p.W475* on NM_020960.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/45 reads (67%) | called by muse, mutect2, varscan2
- GPR151 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- HAPLN4 | c.547C>A p.R183S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- HUWE1 | c.3566C>G p.S1189* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- OSBPL8 | c.2602_2607del p.Q868_K869del | In Frame Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- PLPPR2 | c.761_769del p.V254_V256del | In Frame Del (DEL) | VAF 27/142 reads (19%) | called by mutect2, pindel, varscan2
- RYR3 | c.3763G>C p.E1255Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SIPA1L2 | c.1885_1886insAA p.T629Kfs*20 | Frame Shift Ins (INS) | VAF 9/51 reads (18%) | called by mutect2, varscan2*
- SIPA1L2 | c.1883_1884insAAT p.E628_T629insM | In Frame Ins (INS) | VAF 9/52 reads (17%) | called by mutect2, pindel*, varscan2*
- TNPO1 | c.1947G>A p.M649I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADCY10 | c.4155C>A p.I1385= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV63239321, COSV63244894; called by muse, mutect2, varscan2
- ADGRV1 | c.13263A>G p.P4421= | Silent (SNP) | VAF 55/263 reads (21%) | catalogued as rs781773004, COSV67995370; called by muse, mutect2, varscan2
- AMY2B | c.711C>T p.F237= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as rs770925657, COSV63714342; called by muse, mutect2, varscan2
- API5 | c.6G>A p.P2= | Silent (SNP) | VAF 52/100 reads (52%) | catalogued as rs775001209, COSV66635141, COSV66635464; called by muse, mutect2, varscan2
- BBS4 | c.258C>G p.S86= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV51440451; called by muse, varscan2
- BBX | c.2619A>G p.K873= (on ENST00000325805 / NM_001142568.3; = p.K843= on NM_020235.7) | Silent (SNP) | VAF 48/84 reads (57%) | catalogued as COSV57894764; called by muse, mutect2, varscan2
- C1QTNF1 | c.582C>T p.F194= | Silent (SNP) | VAF 99/185 reads (54%) | catalogued as rs1450258426, COSV59262519; called by muse, mutect2, varscan2
- C2CD6 | c.1353G>A p.Q451= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs372655787; called by mutect2, varscan2
- C7orf26 | c.84C>T p.F28= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100253917, COSV60106048; called by muse, mutect2, varscan2
- C7orf57 | c.114G>A p.A38= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as rs771533681, COSV62364217; called by muse, mutect2, varscan2
- CARMIL2 | c.2289C>T p.I763= | Silent (SNP) | VAF 56/158 reads (35%) | catalogued as COSV58032020; called by muse, mutect2, varscan2
- CHEK2 | c.933C>T p.L311= (on ENST00000382580 / NM_001005735.2; = p.L268= on NM_007194.4) | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV60426384; called by muse, mutect2, varscan2
- CMYA5 | c.2205G>A p.E735= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV71406194; called by muse, mutect2, varscan2
- CNTNAP5 | c.1143C>T p.P381= | Silent (SNP) | VAF 46/74 reads (62%) | catalogued as rs769673214, COSV70477851, COSV70501264; called by muse, mutect2, varscan2
- COL5A3 | c.4803C>T p.S1601= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV53419146; called by muse, mutect2, varscan2
- COPS6 | c.147C>G p.L49= | Silent (SNP) | VAF 161/375 reads (43%) | catalogued as COSV57998909; called by muse, mutect2, varscan2
- DNAH3 | c.6801G>A p.S2267= | Silent (SNP) | VAF 35/47 reads (74%) | catalogued as COSV54513106; called by muse, mutect2, varscan2
- EDNRB | c.1029A>G p.R343= (on ENST00000377211 / NM_001201397.1; = p.R253= on NM_000115.5) | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV57527857; called by muse, mutect2, varscan2
- EP300 | c.5364C>G p.L1788= | Silent (SNP) | VAF 63/92 reads (68%) | catalogued as COSV54345462; called by muse, mutect2, varscan2
- EP300 | c.6123C>G p.L2041= | Silent (SNP) | VAF 58/90 reads (64%) | catalogued as COSV54345477; called by muse, varscan2
- EP300 | c.6174C>G p.L2058= | Silent (SNP) | VAF 61/89 reads (69%) | catalogued as COSV54345492; called by muse, varscan2
- FAM207A | c.168C>A p.T56= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV52422191; called by muse, mutect2, varscan2
- FLRT2 | c.99C>G p.L33= | Silent (SNP) | VAF 60/115 reads (52%) | catalogued as COSV58150120; called by muse, varscan2
- FLRT2 | c.204C>G p.L68= | Silent (SNP) | VAF 71/127 reads (56%) | catalogued as COSV58148983; called by muse, varscan2
- FZD1 | c.822C>T p.F274= | Silent (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- GSDME | c.759C>G p.V253= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV61652923; called by muse, mutect2, varscan2
- HAL | c.1938G>A p.K646= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV54120349; called by muse, mutect2, varscan2
- HSF1 | c.759C>T p.Y253= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as rs781961875, COSV60047371; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.264C>A p.T88= | Silent (SNP) | VAF 73/537 reads (14%) | called by muse, mutect2, varscan2
- KCNQ5 | c.1350C>T p.T450= | Silent (SNP) | VAF 51/122 reads (42%) | catalogued as rs749529273, COSV59682656; called by muse, mutect2, varscan2
- KCNV1 | c.765G>A p.G255= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV52084753; called by muse, mutect2, varscan2
- KCTD19 | c.1101G>A p.L367= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100430987, COSV58575193; called by muse, varscan2
- KIRREL1 | c.1212G>C p.V404= | Silent (SNP) | VAF 47/301 reads (16%) | catalogued as COSV63291360; called by muse, mutect2, varscan2
- LYPD6B | c.477G>A p.Q159= (on ENST00000409029 / NM_001317004.1; = p.Q183= on NM_177964.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/244 reads (30%) | catalogued as rs764636285, COSV54520709; called by muse, mutect2, varscan2
- MAP2K3 | c.573G>A p.V191= (on ENST00000342679 / NM_145109.3; = p.V162= on NM_002756.4) | Silent (SNP) | VAF 42/166 reads (25%) | catalogued as COSV57577552; called by muse, mutect2, varscan2
- MAP3K13 | c.549C>T p.F183= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as COSV53997479; called by muse, mutect2, varscan2
- MEGF8 | c.7767C>T p.V2589= (on ENST00000251268 / NM_001271938.2; = p.V2522= on NM_001410.3) | Silent (SNP) | VAF 114/304 reads (38%) | catalogued as rs1383975242, COSV52101568; called by muse, mutect2, varscan2
- MYT1 | c.3201C>T p.L1067= | Silent (SNP) | VAF 48/371 reads (13%) | catalogued as COSV60513468; called by muse, mutect2, varscan2
- NAALAD2 | c.2208G>A p.L736= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV58966115; called by muse, mutect2, varscan2
- NAV1 | c.1281C>G p.L427= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV55226319; called by muse, varscan2
- NUP188 | c.1704C>T p.I568= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as COSV65364880; called by muse, mutect2, varscan2
- OR2F1 | c.855G>A p.L285= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV67331074; called by muse, mutect2, varscan2
- OR4E2 | c.927G>A p.T309= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs975852343, COSV57731591; called by muse, mutect2
- OR52W1 | c.21C>G p.L7= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV60951637; called by muse, mutect2, varscan2
- OSER1 | c.621G>A p.K207= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV54854815; called by muse, mutect2, varscan2
- PAPSS2 | c.1626C>T p.L542= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as rs7918595, COSV63265139; called by muse, mutect2, varscan2
- PCDHB1 | c.387T>C p.N129= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV60631361; called by muse, mutect2, varscan2
- PCDHGA10 | c.1347C>T p.I449= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as COSV53987225; called by muse, mutect2, varscan2
- PTGER2 | c.225G>A p.V75= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV55420162; called by muse, mutect2, varscan2
- RASL12 | c.30G>C p.A10= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1408961924, COSV54983336; called by muse, mutect2, varscan2
- RFX1 | c.2106C>T p.P702= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV54333568; called by muse, mutect2, varscan2
- RPN1 | c.570C>T p.N190= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV56191602; called by muse, mutect2, varscan2
- RYR3 | c.3534C>T p.F1178= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs1015327748, COSV66785224; called by muse, mutect2, varscan2
- SEMA5A | c.1257C>A p.I419= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV66786760, COSV66805462; called by muse, mutect2, varscan2
- SLC25A29 | c.672C>T p.G224= (on ENST00000359232 / NM_001039355.3; = p.G158= on NM_152333.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs750039229, COSV63650861; called by muse, mutect2, varscan2
- SLU7 | c.1419G>A p.E473= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV51790129; called by muse, mutect2, varscan2
- SOX1 | c.189C>T p.R63= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV58378822; called by muse, mutect2, varscan2
- SPTB | c.2019C>G p.L673= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV67635033; called by muse, mutect2, varscan2
- SSR2 | c.129G>A p.Q43= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV55305002; called by muse, mutect2, varscan2
- THSD7B | c.1704C>T p.A568= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs372552552; called by muse, mutect2, varscan2
- TMEM236 | c.288C>A p.L96= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- TMEM248 | c.921G>A p.E307= | Silent (SNP) | VAF 44/284 reads (15%) | catalogued as rs149604295; called by muse, mutect2, varscan2
- TMPRSS3 | c.942C>G p.L314= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as COSV52307663; called by muse, mutect2, varscan2
- TP73 | c.882C>T p.I294= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV60706126; called by muse, mutect2, varscan2
- URGCP | c.2127C>G p.L709= (on ENST00000453200 / NM_001077663.3; = p.L700= on NM_017920.4) | Silent (SNP) | VAF 36/184 reads (20%) | catalogued as COSV56252690; called by muse, mutect2, varscan2
- USP25 | c.3141C>T p.L1047= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as COSV53490398; called by muse, mutect2, varscan2
- ZNF425 | c.1185C>T p.F395= | Silent (SNP) | VAF 72/186 reads (39%) | catalogued as COSV65201832, COSV65202666; called by muse, mutect2, varscan2
- C16orf82 | c.-61A>T | 5'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- CCNQP1 | n.386G>A | RNA (SNP) | VAF 32/110 reads (29%) | catalogued as rs373944087; called by muse, mutect2, varscan2
- GRM8 | c.727+48381G>A | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as rs747755338, COSV58827657; called by muse, mutect2, varscan2
- OR2U1P | n.539C>G | RNA (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- SH3BP1 | c.*348G>C | 3'UTR (SNP) | VAF 10/12 reads (83%) | catalogued as rs780340184, COSV99312951; called by muse, varscan2
- SLC8A3 | c.1785-2897G>A | Intron (SNP) | VAF 41/74 reads (55%) | catalogued as COSV53692647; called by muse, mutect2, varscan2
- SON | c.6657+159C>T | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99279935; called by muse, mutect2
- SUGCT | c.-1G>C | 5'UTR (SNP) | VAF 6/19 reads (32%) | catalogued as COSV59353687; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 33/41 reads (80%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TTN | c.10361-3988G>C | Intron (SNP) | VAF 19/64 reads (30%) | catalogued as COSV60346068; called by muse, mutect2, varscan2
